Somatic mutation profile of tumor specimen TCGA-12-3649-01A (aliquot TCGA-12-3649-01A-01D-1495-08) from TCGA case TCGA-12-3649, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.2 years (27,846 days).
Specimen TCGA-12-3649-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57125be8-d8ed-4ce6-80a8-eee4bf5757d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-3649-10A (Blood Derived Normal), aliquot TCGA-12-3649-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97b8d9ce-1c3f-4086-a2e2-87e9fc94777c

The open-access MAF lists 86 somatic variants for this specimen: 71 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 61, Silent 15, Nonsense Mutation 6, Splice Site 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 101/290 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1027-2A>G p.X343_splice | Splice Site (SNP) | VAF 19/32 reads (59%) | hotspot (GDC flag); catalogued as rs1085308041, CS090868, CS110214, COSV64293079, COSV64296375; ClinVar: pathogenic; called by muse, varscan2
- ACTR5 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772935923, COSV54762280; called by muse, mutect2, varscan2
- ADAM7 | c.1947C>A p.C649* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV51536658; called by muse, mutect2, varscan2
- ANK2 | c.2968C>G p.R990G | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52154619, COSV52189578; called by muse, mutect2, varscan2
- BLM | c.2500A>T p.N834Y | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61927591; called by muse, mutect2, varscan2
- BMP5 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752442881, COSV63702034; called by muse, mutect2, varscan2
- CALM1 | c.413A>G p.N138S | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.076); catalogued as COSV63663757; called by muse, mutect2, varscan2
- CCDC85A | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs554353955, COSV68151378; called by muse, mutect2, varscan2
- CCSER1 | c.728A>T p.Q243L | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV61470195; called by muse, mutect2, varscan2
- CDH16 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV55339892; called by muse, mutect2, varscan2
- CSMD1 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs781692154, COSV68262082; called by muse, mutect2, varscan2
- CUBN | c.1244G>A p.G415D | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs745602995, COSV64727649; called by muse, mutect2, varscan2
- DIAPH2 | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV61293091; called by muse, mutect2, varscan2
- DMD | c.10775G>C p.R3592T | Missense Mutation (SNP) | VAF 80/113 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58954914; called by muse, mutect2, varscan2
- EPHA10 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60405723; called by muse, mutect2, varscan2
- EPHX4 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as rs765877867, COSV64890106; called by muse, mutect2, varscan2
- GC | c.1277T>C p.L426P | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56739995; called by muse, mutect2, varscan2
- GPR161 | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.084); catalogued as COSV54794867; called by muse, mutect2, varscan2
- GRIK2 | c.2192C>G p.S731C | Missense Mutation (SNP) | VAF 101/295 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV59773988; called by muse, mutect2, varscan2
- HLA-DQA2 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs144060347; called by muse, varscan2
- IGKJ1 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 33/108 reads (31%) | catalogued as rs768964011; called by muse, mutect2, varscan2
- JAG2 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs140813175; called by muse, mutect2, varscan2
- KLF17 | c.82-1G>A p.X28_splice | Splice Site (SNP) | VAF 48/137 reads (35%) | catalogued as COSV64857046; called by muse, mutect2, varscan2
- KLHL1 | c.24C>A p.D8E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV64768781, COSV64779717; called by muse, mutect2, varscan2
- LSR | c.1268C>T p.P423L (on ENST00000361790; = p.P404L on NM_015925.6) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.454); catalogued as rs764830985, COSV55888007; called by muse, mutect2, varscan2
- LYST | c.10192C>T p.R3398* | Nonsense Mutation (SNP) | VAF 93/302 reads (31%) | catalogued as rs1451596846, COSV67703719; called by muse, mutect2, varscan2
- MAGEB16 | c.452T>A p.F151Y | Missense Mutation (SNP) | VAF 46/66 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV67874650; called by muse, mutect2, varscan2
- MAGEC2 | c.713T>A p.F238Y | Missense Mutation (SNP) | VAF 105/147 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56001580; called by muse, mutect2, varscan2
- MEP1B | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320548902, COSV52499975; called by muse, mutect2, varscan2
- MISP | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs772124174, COSV53119376; called by muse, mutect2, varscan2
- MMS22L | c.3097C>T p.R1033* | Nonsense Mutation (SNP) | VAF 39/115 reads (34%) | catalogued as rs146474162, COSV51526670; called by muse, mutect2, varscan2
- MST1R | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 95/249 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs751907940, COSV56569560; called by muse, mutect2, varscan2
- MYH3 | c.5414C>T p.A1805V | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs781063695, COSV56870191; called by muse, mutect2, varscan2
- OR52H1 | c.13A>C p.N5H (on ENST00000322653; = p.N11H on NM_001005289.1) | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59506280; called by muse, mutect2, varscan2
- OR52I2 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 101/338 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as rs138555035; called by muse, mutect2
- OR6K2 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs778393764, COSV100656924, COSV62744127; called by muse, mutect2, varscan2
- OR8A1 | c.653C>A p.T218N | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as COSV52510538; called by muse, mutect2, varscan2
- PCDHGA1 | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 118/378 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); catalogued as rs766357788, COSV65295536; called by muse, mutect2, varscan2
- PCLO | c.13637C>T p.T4546M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as rs576824740, COSV61620329; called by muse, mutect2, varscan2
- PHLPP2 | c.572C>G p.T191S | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.137); catalogued as rs757331662, COSV62427326; called by muse, mutect2
- PLEKHA5 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs752042146, COSV54711427; called by muse, mutect2, varscan2
- PMM1 | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53449514; called by muse, mutect2, varscan2
- PPP4R4 | c.590T>A p.L197* | Nonsense Mutation (SNP) | VAF 61/172 reads (35%) | catalogued as COSV58558431; called by muse, mutect2, varscan2
- RYR2 | c.4990G>A p.V1664I | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs749434532, COSV63698965, COSV63705585; called by muse, mutect2, varscan2
- RYR2 | c.14833C>G p.Q4945E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV63661988, COSV63715070; called by muse, mutect2, varscan2
- SALL4 | c.3056C>G p.S1019C | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53856306; called by muse, mutect2, varscan2
- SCN9A | c.1659T>A p.S553R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV57625051; called by muse, mutect2, varscan2
- SERPINA11 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58242138, COSV58243338; called by muse, mutect2, varscan2
- SIPA1L1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV62173831; called by muse, mutect2, varscan2
- SLC27A2 | c.836G>A p.C279Y | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1252465975, COSV51063254; called by muse, mutect2, varscan2
- SLC2A1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1017082606, COSV65288531; called by muse, mutect2, varscan2
- SLC4A10 | c.2704A>T p.K902* (on ENST00000446997 / NM_001354461.2; = p.K872* on NM_022058.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/31 reads (58%) | catalogued as COSV55800657; called by muse, mutect2, varscan2
- SORCS2 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1399506534, COSV61183689; called by muse, mutect2
- SPRY3 | c.419C>A p.P140H | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV57144517; called by muse, mutect2, varscan2
- SULT1C3 | c.403G>T p.V135F | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV61254715; called by muse, mutect2, varscan2
- TESK1 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs764988346, COSV52412241; called by muse, mutect2, varscan2
- TMEM26 | c.690C>A p.N230K | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.107); catalogued as COSV53264426; called by muse, mutect2, varscan2
- TRIM6 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748199490, COSV53475055; called by muse, mutect2, varscan2
- TRIM6 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as rs973284825, COSV53479248; called by muse, mutect2, varscan2
- TSSK1B | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs371461523; called by muse, mutect2, varscan2
- TTN | c.54896A>T p.H18299L (on ENST00000591111; = p.H10875L on NM_003319.4) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | PolyPhen benign (0.436); catalogued as COSV60360252; called by muse, mutect2, varscan2
- TUBA3C | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 83/245 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.117); catalogued as rs756491837, COSV67139538; called by muse, mutect2, varscan2
- USP20 | c.2372C>T p.A791V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.985); catalogued as rs745311962, COSV59619377; called by muse, mutect2, varscan2
- VRTN | c.502A>G p.S168G | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56443846; called by muse, mutect2, varscan2
- ZFC3H1 | c.1954G>C p.D652H | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV66436024; called by muse, mutect2, varscan2
- ZGRF1 | c.4882C>A p.Q1628K | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.207); catalogued as COSV58343047, COSV58343138; called by muse, mutect2
- ZSCAN5B | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 25/172 reads (15%) | catalogued as rs555339343, COSV62841011; called by muse, mutect2, varscan2
- BRPF3 | c.1612del p.Q538Rfs*8 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- C12orf50 | c.536_537del p.I179Kfs*11 | Frame Shift Del (DEL) | VAF 52/189 reads (28%) | called by mutect2, pindel, varscan2
- TBC1D19 | c.668T>G p.L223R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- ANKRD13B | c.1170T>A p.I390= | Silent (SNP) | VAF 47/135 reads (35%) | catalogued as COSV61472108; called by muse, mutect2, varscan2
- CBLN2 | c.153G>A p.A51= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV54052027; called by muse, mutect2, varscan2
- CEACAM18 | c.792G>A p.K264= | Silent (SNP) | VAF 84/312 reads (27%) | catalogued as COSV67284251; called by muse, mutect2, varscan2
- CHRNA10 | c.1047C>T p.C349= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as rs555234421, COSV51707349; called by muse, mutect2
- CPAMD8 | c.1905A>G p.S635= (on ENST00000651564; = p.S588= on NM_015692.5) | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV52240024; called by muse, mutect2, varscan2
- CR2 | c.1251C>A p.L417= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as COSV65509703; called by muse, mutect2, varscan2
- GCN1 | c.2259T>A p.P753= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV56115100; called by muse, mutect2, varscan2
- ITIH1 | c.804C>T p.C268= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as rs752722689, COSV56258649; called by muse, mutect2, varscan2
- JAG2 | c.2598C>T p.I866= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as rs369469630; called by muse, mutect2, varscan2
- MTNR1B | c.312C>T p.D104= | Silent (SNP) | VAF 121/297 reads (41%) | catalogued as rs139515067; called by muse, mutect2, varscan2
- MUC3A | c.7485G>A p.S2495= | Silent (SNP) | VAF 62/216 reads (29%) | catalogued as rs79067082, COSV60210457; called by muse, mutect2, varscan2
- MYO10 | c.972G>A p.R324= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV72563640; called by muse, mutect2
- NBPF10 | c.11073A>T p.G3691= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs781839675, COSV61673670; called by muse, mutect2
- TGIF2LX | c.492G>A p.K164= | Silent (SNP) | VAF 24/36 reads (67%) | catalogued as COSV52213391, COSV52215223; called by muse, mutect2, varscan2
- ZNF493 | c.612T>C p.I204= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as COSV62752440; called by muse, mutect2, varscan2
